Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6461, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6461-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]	
[REDACTED]	
Case ID	[REDACTED]
[REDACTED]	[REDACTED]

[page 2 of 3]
Formatted Path Report

LARGE INTESTINE TISSUE CHECKLIST

Specimen type: Hemicolectomy

Specimen size: Not specified

Tumor site: Hepatic flexure

Tumor size: 7 x 8 x 2 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Invades other organs (specify)

Lymph nodes: 4/4 positive for metastasis (Intraabdominal 4/4)

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Tumor invades the liver.

[page 3 of 3]
Laterality	Date of Procurement
NA	■■■

Source: NCI Genomic Data Commons file bd7103ff-19aa-44de-afa9-6eaaab2573c4 (TCGA-F4-6461.2A2E4B4C-ECA6-4E8B-A84F-193C7C87B6B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).